Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4707, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4707-01A (Primary Tumor).

FINAL DIAGNOSIS**PART 1:****CYSTIC WALL, EXCISION-**

- A. FIBROVASCULAR TISSUE LINED BY CUBOIDAL AND COLUMNAR EPITHELIUM, CONSISTENT WITH BENIGN CYST.
- B. NO EVIDENCE OF NEOPLASIA IS SEEN.

PART 2:**KIDNEY, RIGHT, LARGER UPPER POLE TUMOR, PARTIAL NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH CYSTIC CHANGES.
- B. FUHRMAN NUCLEAR GRADE IS II OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.7 cm.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- F. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- G. TNM STAGE: pT1b NX MX.

PART 3:**KIDNEY, RIGHT, SMALLER UPPER POLE TUMOR, PARTIAL NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH CYSTIC CHANGES.
- B. FUHRMAN NUCLEAR GRADE IS II OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 2.1 cm.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- F. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- G. TNM STAGE: pT1a NX MX.

PART 4:**FAT OVERLYING MIDPOLE TUMOR, EXCISION-**

- A. MATURE ADIPOSE TISSUE WITH NO FOCAL HEMORRHAGE.
- B. NO EVIDENCE OF CARCINOMA IS SEEN.

PART 5:**KIDNEY, RIGHT, MID POLE TUMOR, PARTIAL NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH CYSTIC AND MYXOID CHANGES.
- B. FUHRMAN NUCLEAR GRADE IS III OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.1 cm.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. THE CARCINOMA FOCALLY EXTENDS TO THE INKED CAPSULAR RESECTION MARGIN (SLIDE 5C). THE PARENCHYMAL SURGICAL MARGINS IS FREE OF THE NEOPLASM.
- F. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- G. TNM STAGE: pT1b NX MX.

PART 6:**KIDNEY, LEFT, RADICAL NEPHRECTOMY -**

- H. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH EXTENSIVE NECROSIS, HEMORRHAGE AND SARCOMATOID FEATURES INCLUDING FOCAL RHABDROID MORPHOLOGY (See comment).
- I. FUHRMAN NUCLEAR GRADE IS IV OF IV.
- J. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.2 cm.
- K. THE CARCINOMA EXTENDS TO THE RENAL SINUS FAT (SLIDE 6E).
- L. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- M. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- N. FOCI SUSPICIOUS FOR ANGIOLYMPHATIC INVASION ARE IDENTIFIED.
- O. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- P. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- Q. LEFT ADRENAL WITH NO SPECIFIC PATHOLOGIC CHANGES.
- R. TNM STAGE: pT3a NX MX.

Source: NCI Genomic Data Commons file f68848b3-ea40-4f72-8103-8927bfb13c8a (TCGA-B0-4707.34547C2A-5196-46D4-9FC4-F336F99AF712.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).